Gene-level copy-number profile of tumor specimen TCGA-31-1951-01A from TCGA case TCGA-31-1951, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 58.5 years (21,352 days).
Specimen TCGA-31-1951-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.32f2ebdc-08fd-4130-a2b2-8a3b054846c4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-31-1951-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bbf3e404-538d-45c9-9f37-a1326c7e0327

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 122; copy number 1: 13,207; copy number 2: 39,200; copy number 3: 5,303; copy number 4: 1,804; copy number 5: 160; copy number 6: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-31-1951-01): tumor purity 0.8, ploidy 1.97, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 118 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:85,378,327–85,448,961, 2 genes (within-gene range 0–1): LINC02647, AC025428.1.
- chr10:86,749,754–90,628,852, 105 genes (broad region; genes not listed).
- chr16:78,793,584–79,110,882, 11 genes: AC009141.1, RPS3P7, AC136603.1, AC027279.4, AC027279.1, AC027279.3, AC027279.2, AC009145.4, AC009145.3, AC009145.1, AC009145.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 175 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:136,946,230–137,011,085, 2 genes, copy number 5: IL20RB, IL20RB-AS1.
- chr5:12,297,399–13,944,543, 12 genes, copy number 5: RNU6-679P, AC106771.1, LINC01194, AC106794.2, AC106794.1, LINC02220, AC016553.1, RPS23P5, NENFP3, AC016546.1, DNAH5, AC016576.1.
- chr14:99,158,416–99,942,060, 15 genes, copy number 6 (within-gene range 4–6): AL162151.1, BCL11B, AL109767.1, AL132819.1, SETD3, RNU6-91P, CCNK, CCDC85C, AL110504.1, Y_RNA, AL160313.1, HHIPL1, CYP46A1, AL160313.2, EML1.
- chr19:14,402,717–16,328,685, 108 genes, copy number 5 (broad region; genes not listed).
- chr20:25,062,962–26,086,917, 38 genes, copy number 5 (within-gene range 1–5): AL080312.2, VSX1, AL080312.1, AL035252.2, AL035252.1, AL035252.5, ENTPD6, Y_RNA, AL035252.4, AL035252.3, AL121772.1, PYGB, AL121772.2, AL121772.3, ABHD12, PPIAP2, GINS1, NINL, RNU6ATAC17P, NANP, ZNF337-AS1, RN7SL594P, MED28P7, ZNF337, AL031673.1, AL390198.1, VN1R108P, FAM182B, BSNDP1, AL390198.2, BSNDP2, CFTRP1, LINC01733, FAM182A, AL078587.1, AL078587.2, AL450124.1, BSNDP3.

Autosomal genes at a single copy (total copy number 1): 12,704. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
